Somatic mutation profile of tumor specimen TARGET-20-PARWAS-09A (aliquot TARGET-20-PARWAS-09A-01D) from TARGET case TARGET-20-PARWAS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,332 days).
Specimen TARGET-20-PARWAS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4018ac1f-7b7a-4fc4-aa3b-5fa81bb745c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARWAS-14A (Bone Marrow Normal), aliquot TARGET-20-PARWAS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ff6bec1-dc74-44a8-817b-8122faf30421

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ISY1-RAB43 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV56441625; called by muse, mutect2
- ARHGEF33 | c.639C>G p.G213= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- CRLF1 | c.1140C>T p.C380= | Silent (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- HIVEP1 | c.603A>G p.K201= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV65100194; called by muse, mutect2
- LAMB2 | c.4761G>A p.L1587= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
